Gene-level copy-number profile of tumor specimen ALCH-AE0U-TTP1-B from ALCHEMIST case ALCH-AE0U, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 56.8 years (20,746 days).
Specimen ALCH-AE0U-TTP1-B: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 21747dcf-ebd0-4bac-9bf1-1d3adadba510.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AE0U-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,239 have no estimate.
https://portal.gdc.cancer.gov/files/5bbbfad5-49c7-46d5-8390-97af72f97a3a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 28; copy number 1: 15,328; copy number 2: 38,755; copy number 3: 4,254; copy number 4: 9; copy number 5: 9; copy number 8: 1.

Homozygous deletions (total copy number 0; autosomes only): 28 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:130,107,684–130,109,741, 2 genes (within-gene range 0–2): POTEF-AS1, RNU6-1049P.
- chr4:52,680,609–52,692,999, 1 gene: AC104066.3.
- chr7:45,789,585–45,821,064, 4 genes: RNU6-241P, CICP20, AC096582.1, AC096582.2.
- chr7:63,768,257–63,771,047, 1 gene: CICP24.
- chr9:133,079,900–133,163,914, 3 genes (within-gene range 0–1): CELP, RALGDS, AL162417.1.
- chr9:137,230,757–137,247,770, 3 genes: SLC34A3, TUBB4B, FAM166A.
- chr14:106,443,133–106,461,055, 2 genes (within-gene range 0–2): IGHV3-41, HOMER2P1.
- chr16:560,394–584,109, 4 genes: PRR35, PIGQ, NHLRC4, Z98883.1.
- chr16:87,834,592–87,837,663, 2 genes (within-gene range 0–2): MIR6775, AC126696.2.
- chr17:39,737,927–39,747,291, 1 gene: GRB7.
- chr21:33,152,614–33,170,649, 2 genes: AP000290.1, LINC01548.
- chr21:44,989,864–45,004,727, 3 genes: LINC00163, LINC00165, PICSAR.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 10 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:96,992,864–96,996,601, 1 gene, copy number 5: AL049833.3.
- chr16:10,718,633–10,725,296, 8 genes, copy number 5: MTCYBP33, MTND6P33, MTND5P33, MTND4P34, MTND4LP24, MTND3P13, MTCO3P24, MTATP6P24.
- chr22:15,721,486–15,722,608, 1 gene, copy number 8: AP000529.1.

Autosomal genes at a single copy (total copy number 1): 15,328. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
